Somatic mutation profile of tumor specimen 6530147a-efe9-4df6-ac2f-03ece3 (aliquot 6530147a-efe9-4df6-ac2f-03ece3_D6) from CPTAC case 17OV015, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 6530147a-efe9-4df6-ac2f-03ece3: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bfd7136f-bc8e-4257-904f-4325c0c50f27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 63e27b5b-492d-455a-9881-185955 (Blood Derived Normal), aliquot 63e27b5b-492d-455a-9881-185955_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09d182f6-347d-45ea-90f4-7ea62d604dd5

The open-access MAF lists 81 somatic variants for this specimen: 58 protein-altering or splice-affecting, 13 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 13, Intron 6, Splice Site 4, Nonsense Mutation 3, 5'UTR 3, Splice Region 2, 3'UTR 1, Frame Shift Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATG9B | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 30/346 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765604444; called by muse, mutect2
- BCAS2 | c.476A>G p.H159R | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs778396031, COSV65767742; called by mutect2, varscan2
- CACNA1S | c.2836G>A p.G946S | Missense Mutation (SNP) | VAF 45/338 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs569324688, COSV100755441; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL19A1 | c.1224+1G>T p.X408_splice | Splice Site (SNP) | VAF 13/117 reads (11%) | catalogued as rs766625405; called by muse, mutect2, varscan2
- COPS7A | c.755G>T p.R252L | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV57526909; called by muse, mutect2, varscan2
- FAT4 | c.14283G>T p.M4761I | Missense Mutation (SNP) | VAF 135/518 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1282895291; called by muse, mutect2, varscan2
- FZD1 | c.1580C>A p.T527N | Missense Mutation (SNP) | VAF 62/516 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99842437; called by muse, mutect2, varscan2
- IGFBP1 | c.362C>G p.P121R | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.174); catalogued as rs531101667, COSV99034475; called by muse, mutect2, varscan2
- KIAA1841 | c.1455C>G p.D485E | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs147230498; called by muse, mutect2
- KIF3B | c.1474C>G p.L492V | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as COSV100996498; called by muse, mutect2, varscan2
- NAV2 | c.6788C>G p.S2263W (on ENST00000396087 / NM_001244963.2; = p.S2204W on NM_145117.5) | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV104408412; called by muse, mutect2
- NBEAL2 | c.3869G>A p.R1290Q | Missense Mutation (SNP) | VAF 33/364 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as rs765816712; called by muse, mutect2
- NTSR1 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 91/389 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1208532915, COSV65138047; called by muse, mutect2, varscan2
- PIK3R2 | c.941C>T p.T314I | Missense Mutation (SNP) | VAF 17/206 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1338759825; called by muse, mutect2
- PPP2R3B | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs372414725, COSV66813629, COSV66814003; called by muse, mutect2
- SMG6 | c.4096G>C p.D1366H | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99557517; called by muse, mutect2
- TENM1 | c.2786C>G p.A929G | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV100949699, COSV100950025; called by muse, varscan2
- TP53 | c.558del p.D186Efs*61 | Frame Shift Del (DEL) | VAF 296/758 reads (39%) | catalogued as COSV52677455, COSV53407442; called by mutect2, varscan2
- TRPM4 | c.2117G>A p.R706H | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.155); catalogued as rs79868934; called by muse, mutect2
- XYLT1 | c.2563G>T p.A855S | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as COSV54490798; called by muse, mutect2
- ANKRD30A | c.3680G>C p.G1227A (on ENST00000611781; = p.G1171A on NM_052997.2) | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- ARHGEF38 | c.871T>G p.L291V | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- BST2 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- C1orf116 | c.692A>G p.H231R | Missense Mutation (SNP) | VAF 48/332 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- C9orf116 | c.111G>C p.R37S | Missense Mutation (SNP) | VAF 31/276 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- C9orf135 | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDHR4 | c.1894G>C p.A632P | Missense Mutation (SNP) | VAF 38/244 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- CLASP1 | c.2188A>T p.T730S | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- CMTR1 | c.1562+1G>C p.X521_splice | Splice Site (SNP) | VAF 7/100 reads (7%) | called by muse, mutect2
- CT45A10 | c.331G>C p.G111R | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- DCC | c.1598A>T p.N533I | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- EPG5 | c.6371T>G p.M2124R | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- FANK1 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT4 | c.14282T>A p.M4761K | Missense Mutation (SNP) | VAF 135/515 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FCHO1 | c.-88C>A | Splice Region (SNP) | VAF 13/248 reads (5%) | called by muse, mutect2
- FRY | c.7646C>G p.T2549R | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- FSIP2 | c.15415C>G p.L5139V | Missense Mutation (SNP) | VAF 15/224 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.578); called by muse, mutect2
- GREB1L | c.3997T>C p.F1333L | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- HCK | c.1246+1G>T p.X416_splice | Splice Site (SNP) | VAF 18/102 reads (18%) | called by muse, mutect2, varscan2
- HECTD1 | c.1248T>A p.C416* | Nonsense Mutation (SNP) | VAF 4/55 reads (7%) | called by muse, mutect2
- IFI6 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.114); called by muse, mutect2
- KDM4A | c.427A>T p.K143* | Nonsense Mutation (SNP) | VAF 15/135 reads (11%) | called by muse, mutect2, varscan2
- LCOR | c.823A>C p.N275H | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- LZTS3 | c.987G>A p.W329* | Nonsense Mutation (SNP) | VAF 36/367 reads (10%) | called by muse, mutect2
- MAP2K2 | c.614G>T p.R205I | Missense Mutation (SNP) | VAF 29/484 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2
- MOGAT1 | c.877C>G p.Q293E | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- PDLIM3 | c.359G>C p.G120A (on ENST00000284770 / NM_001257963.1; = p.G287A on NM_014476.6) | Missense Mutation (SNP) | VAF 29/310 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2
- PITPNM1 | c.1241A>C p.D414A | Missense Mutation (SNP) | VAF 49/372 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RESF1 | c.3119A>G p.E1040G | Missense Mutation (SNP) | VAF 13/197 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.189); called by muse, mutect2
- SLC25A47 | c.830G>T p.G277V | Missense Mutation (SNP) | VAF 25/594 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SPAG16 | c.1180A>C p.T394P | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); called by muse, mutect2
- TCHHL1 | c.1864A>G p.T622A | Missense Mutation (SNP) | VAF 110/569 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TEX51 | c.482C>A p.T161N (on ENST00000643416; = p.T137N on NM_001322244.2) | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.311); called by muse, mutect2
- TMEM132A | c.2783G>T p.G928V (on ENST00000453848 / NM_178031.3; = p.G929V on NM_017870.4) | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- VPS11 | c.784G>A p.E262K (on ENST00000620429; = p.E806K on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.495); called by muse, mutect2
- ZFP30 | c.136+1G>C p.X46_splice | Splice Site (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- ZNF417 | c.28A>G p.T10A | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZSCAN5A | c.591A>T p.G197= | Splice Region (SNP) | VAF 19/161 reads (12%) | called by muse, mutect2, varscan2
- BRICD5 | c.267C>T p.N89= | Silent (SNP) | VAF 33/178 reads (19%) | catalogued as rs1329620949; called by mutect2, varscan2
- C2orf69 | c.915A>G p.G305= | Silent (SNP) | VAF 28/247 reads (11%) | called by muse, mutect2, varscan2
- COL1A2 | c.2856C>T p.G952= | Silent (SNP) | VAF 126/1054 reads (12%) | catalogued as rs1800241, COSV51959235; called by muse, mutect2, varscan2
- COL6A2 | c.732A>G p.G244= | Silent (SNP) | VAF 33/316 reads (10%) | called by muse, mutect2, varscan2
- DNAJC14 | c.129A>C p.A43= | Silent (SNP) | VAF 22/260 reads (8%) | called by muse, mutect2
- HAUS5 | c.630C>T p.G210= | Silent (SNP) | VAF 22/185 reads (12%) | called by muse, mutect2, varscan2
- JCAD | c.1908C>G p.A636= | Silent (SNP) | VAF 38/352 reads (11%) | called by muse, mutect2, varscan2
- LAMA2 | c.4698C>G p.R1566= | Silent (SNP) | VAF 26/366 reads (7%) | catalogued as COSV70353424; called by muse, mutect2
- LRRTM4 | c.1020G>A p.A340= | Silent (SNP) | VAF 42/382 reads (11%) | catalogued as rs1328534247, COSV69140915; called by muse, mutect2, varscan2
- NTF3 | c.345G>A p.P115= | Silent (SNP) | VAF 103/460 reads (22%) | catalogued as rs772851614, COSV58417151; called by muse, varscan2
- OPRK1 | c.564T>A p.S188= | Silent (SNP) | VAF 35/225 reads (16%) | called by muse, mutect2
- PRPF31 | c.378G>A p.E126= | Silent (SNP) | VAF 61/524 reads (12%) | called by muse, mutect2, varscan2
- RHBDF2 | c.2163C>T p.A721= | Silent (SNP) | VAF 27/198 reads (14%) | catalogued as rs758075888; called by muse, mutect2, varscan2
- ACTN2 | c.698-1156T>G | Intron (SNP) | VAF 7/118 reads (6%) | called by muse, mutect2
- ANK1 | c.5619+186C>G | Intron (SNP) | VAF 98/723 reads (14%) | catalogued as rs771066484; called by muse, mutect2, varscan2
- COBLL1 | c.64+13G>A | Intron (SNP) | VAF 85/272 reads (31%) | called by muse, mutect2, varscan2
- FGFR3 | c.*1058G>T | 3'UTR (SNP) | VAF 88/642 reads (14%) | called by muse, mutect2, varscan2
- MTMR6 | c.-32T>G | 5'UTR (SNP) | VAF 17/119 reads (14%) | called by muse, mutect2, varscan2
- NEDD4L | c.49-16248G>C | Intron (SNP) | VAF 23/117 reads (20%) | called by muse, mutect2, varscan2
- RET | c.-49C>A | 5'UTR (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- SSH2 | c.107+32646G>C | Intron (SNP) | VAF 13/133 reads (10%) | called by muse, mutect2
- TFAP2A | c.889+193T>C | Intron (SNP) | VAF 28/276 reads (10%) | catalogued as rs1044948696; called by mutect2, varscan2
- XIRP2 | c.-97T>C | 5'UTR (SNP) | VAF 18/79 reads (23%) | catalogued as rs1442109157; called by muse, mutect2, varscan2
